Gene-level copy-number profile of tumor specimen TCGA-78-7154-01A from TCGA case TCGA-78-7154, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 72.5 years (26,481 days).
Specimen TCGA-78-7154-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.7ff54d62-a495-46f8-ac16-59f5d4dd03bf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-78-7154-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b5d01340-16f5-467a-8179-fa2338e1cbd8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 115; copy number 2: 7,940; copy number 3: 18,021; copy number 4: 20,237; copy number 5: 6,787; copy number 6: 2,893; copy number 7: 1,602; copy number 8: 854; copy number 9: 69; copy number 10: 553; copy number 11: 45; copy number 12: 60; copy number 13: 230; copy number 14: 1; copy number 15: 25; copy number 17: 3; copy number 19: 131; copy number 21: 108; copy number 23: 43; copy number 25: 8; copy number 26: 19; copy number 27: 52; copy number 32: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-78-7154-01A-11D-2035-01): tumor purity 0.5, ploidy 3.82, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:81,666,477–82,866,508, 14 genes: AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,355 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:41,143,780–41,157,555, 1 gene, copy number 14: HNRNPA1P57.
- chr2:55,865,967–60,554,467, 42 genes, copy number 10: EFEMP1, RN7SKP208, AC011306.1, MIR217HG, MIR217, MIR216A, MIR216B, LINC01813, AC007744.1, AC007743.1, CCDC85A, RNA5SP93, PPIAP63, EIF2S2P7, AC132153.1, AC068276.1, AC073875.1, ACTG1P22, VRK2, AC068193.1, FANCL, AC007250.1, EIF3FP3, LINC01795, LINC01122, AC007238.1, AC007092.1, LINC01793, AC007100.1, AC007179.2, AC007179.1, AC007179.3, RNU6-508P, RNA5SP94, AC007100.2, AC007132.1, MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1.
- chr2:61,868,085–61,888,671, 1 gene, copy number 15 (within-gene range 8–15): CCT4.
- chr2:61,878,940–67,684,077, 112 genes, copy number 10–15 (within-gene range 8–15) (broad region; genes not listed).
- chr4:70,815,783–82,340,013, 174 genes, copy number 13–23 (broad region; genes not listed).
- chr7:65,773,620–66,958,551, 45 genes, copy number 11 (within-gene range 3–11): GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248.
- chr7:92,131,774–92,245,924, 1 gene, copy number 19 (within-gene range 3–19): AC000120.3.
- chr7:92,198,969–100,797,797, 231 genes, copy number 19–26 (broad region; genes not listed).
- chr7:109,521,981–109,660,802, 2 genes, copy number 23: AC073071.1, AC073387.1.
- chr7:110,590,082–112,896,625, 26 genes, copy number 19 (within-gene range 3–19): AC073326.2, IMMP2L, AC073326.1, LRRN3, AC003989.2, AC003989.1, DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168.
- chr7:114,922,359–119,907,397, 70 genes, copy number 9–32 (broad region; genes not listed).
- chr7:125,917,871–127,253,093, 8 genes, copy number 25 (within-gene range 3–25): AC003975.1, AC000372.1, GRM8, AC002057.2, AC000374.1, AC002057.1, AC000367.1, AC000362.1.
- chr7:129,604,548–131,496,632, 56 genes, copy number 10 (within-gene range 5–10): AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335, COPG2, AC007938.3, AUXG01000058.1, RNA5SP246, AC234644.1, TSGA13, AC234644.2, KLF14, AC016831.5, AC016831.6, AC016831.2, H4P1, AC016831.3, LINC00513, MIR29A, AC016831.1, MIR29B1, AC016831.4, AC058791.1, LINC-PINT, RNU6-1010P, MKLN1, AC009362.1, MKLN1-AS.
- chr7:138,298,088–138,442,238, 3 genes, copy number 17: AC008155.1, PTMAP10, IMPDH1P3.
- chr7:139,777,051–140,062,951, 2 genes, copy number 9: TBXAS1, PARP12.
- chr7:140,094,697–140,094,792, 1 gene, copy number 9: Y_RNA.
- chr8:105,546,089–106,770,244, 14 genes, copy number 9: ZFPM2-AS1, AC103853.1, AC103853.2, RPL12P24, AC090802.1, Y_RNA, SLC16A14P1, AC027031.1, AC027031.2, OXR1, AC090579.1, TAGLN2P1, RNU7-84P, ABRA.
- chr8:124,044,395–126,558,478, 48 genes, copy number 9 (within-gene range 7–9): FER1L6-AS2, AC100871.1, ARF1P3, AC090921.1, RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2.
- chr8:126,582,631–126,846,981, 3 genes, copy number 9: AC083923.1, RNU11-4P, AC024382.1.
- chr8:132,024,216–135,742,495, 58 genes, copy number 12: OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P.
- chr8:135,977,329–136,295,232, 2 genes, copy number 12 (within-gene range 11–12): AC103955.1, AC023781.1.
- chr17:31,303,770–40,975,926, 394 genes, copy number 10–13 (within-gene range 6–13) (broad region; genes not listed).
- chr20:21,947,647–23,990,454, 61 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 115. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
